TCGA case TCGA-DG-A2KL — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Ontario Institute for Cancer Research. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2da977fc-8b46-4c40-9636-b12fd36a98e4

Demographics
Sex at birth: female; Country of residence at enrollment: Canada; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 53.5 years (19,539 days); Method of diagnosis: Dilation and Curettage Procedure; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; FIGO stage: Stage IIA; FIGO staging edition year: 1995; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 8; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 141 days; Days to treatment end: 169 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 141 days; Days to treatment end: 177 days; Treatment dose: 4,500 cGy; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 179 days; Days to treatment end: 193 days; Treatment dose: 2,100 cGy; Number of fractions: 3; Treatment anatomic sites: Primary Tumor Field.

Follow-up (6 entries)
- Days to follow up: 1,367 days (3.7 years); Disease response: Tumor Free.
- Imaging type: CT Scan; Timepoint: Preoperative.
- Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Bladder Involvement; Timepoint: Preoperative.
- Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Parametrium Involvement; Timepoint: Preoperative.
- ECOG performance status: 0; Timepoint: Prior to Adjuvant Therapy.
- Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement; Timepoint: Preoperative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Weight: 75 kg; Height: 155 cm; BMI: 31.2.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 25.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DG-A2KL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 380 mg.
  Slide TCGA-DG-A2KL-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 25; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 20.
- Sample TCGA-DG-A2KL-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DG-A2KL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 5; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 5; Tobacco smoking history indicator: 2; Performance status timing: Pre-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Dilation and curettage; Margins involved hysterectomy: Positive vaginal margin; Lymph nodes examined: Yes; Lymphovascular invasion: Present; Corpus involvement: Absent; New tumor event diagnosis indicator: No.
- Diagnostic ct result outcomes: Ct scan preop results: Bladder Absent; Ct scan preop results: Parametrium Absent; Ct scan preop results: Pelvic Nodes Absent.
- Follow-up form: Lost to follow-up: Yes; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Follow-up form, Treatment, Radiation therapy info: Radiation therapy xrt type: External beam radiation.
- Follow-up form, Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent fractions total: 5.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,367 days; disease-specific survival: no event (censored), 1,367 days; disease-free interval: no event (censored), 1,367 days; progression-free interval: no event (censored), 1,367 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DG-A2KL-01A-11D-A17U-01): tumor purity 0.53, ploidy 3.32, whole-genome doublings 1.
